Somatic mutation profile of tumor specimen C3L-09811-01 (aliquot CPT0546820009) from CPTAC case C3L-09811, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.0 years (26,290 days).
Specimen C3L-09811-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4896343e-d85e-45b5-a3b0-0ef098c81780.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09811-31 (Blood Derived Normal), aliquot CPT0546970004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6d3842f-e3de-4365-8bd0-d4e51940b283

The open-access MAF lists 195 somatic variants for this specimen: 137 protein-altering or splice-affecting, 48 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 48, Nonsense Mutation 8, Intron 6, Frame Shift Del 3, RNA 2, Splice Region 2, 3'UTR 1, Translation Start Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 88/283 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/364 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PIEZO2 | c.7067C>T p.T2356M | Missense Mutation (SNP) | VAF 146/341 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878853137, CM144710, COSV53286754, COSV53287180; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNGAP1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 45/542 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs1554120589; ClinVar: likely pathogenic; called by muse, mutect2
- AC004593.2 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 206/567 reads (36%) | catalogued as COSV56089052; called by muse, mutect2, varscan2
- ACAN | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 156/560 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771509541, COSV61360520; called by muse, mutect2
- ADAMTSL1 | c.4072C>T p.L1358F | Missense Mutation (SNP) | VAF 137/445 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.425); catalogued as rs1258103548; called by muse, mutect2, varscan2
- ADGRV1 | c.13507A>C p.S4503R | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs764716759, COSV67979835, COSV67980159, COSV67983377; called by muse, mutect2, varscan2
- ALPK1 | c.1904G>A p.G635D | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1471898828; called by muse, mutect2, varscan2
- ANO5 | c.739T>C p.S247P | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.52); catalogued as rs1326315048, COSV100202115, COSV61082087; called by muse, mutect2, varscan2
- CEP104 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 151/317 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58215106; called by muse, mutect2, varscan2
- CHRNB4 | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 158/504 reads (31%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.994); catalogued as COSV55716141; called by muse, mutect2, varscan2
- COL22A1 | c.3598C>T p.P1200S | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1316026996; called by muse, mutect2
- CTTN | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 57/463 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367827428, COSV57235745; called by muse, mutect2, varscan2
- DCAF4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 135/308 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs780835122, COSV62320549; called by muse, mutect2, varscan2
- DNAH17 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759303219; called by muse, mutect2, varscan2
- EIF2AK3 | c.2909C>T p.T970M | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs751166753, COSV57544965; called by muse, mutect2
- EIF3C | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 220/1268 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.132); catalogued as rs1245645302; called by mutect2, varscan2
- EPHA10 | c.2368G>A p.G790R | Missense Mutation (SNP) | VAF 180/435 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs777625036; called by muse, mutect2, varscan2
- FLNC | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 118/436 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57952737; called by muse, mutect2, varscan2
- GABRA6 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1270279109, COSV50877438, COSV99194040; called by muse, mutect2, varscan2
- GATA4 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 197/639 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs749821814; called by muse, mutect2, varscan2
- IHH | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 52/645 reads (8%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.684); catalogued as rs200898513, COSV55393501; called by muse, mutect2
- KCNS1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 676/1187 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV60259478; called by muse, varscan2
- KIAA1671 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 201/461 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1257724112; called by muse, mutect2, varscan2
- KL | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 151/758 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV101199238; called by muse, varscan2
- LARGE1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs765312193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LBP | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 349/675 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.4); catalogued as rs754740570; called by muse, mutect2, varscan2
- LRRK2 | c.5744G>A p.R1915K | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.43); catalogued as rs1225568930; called by muse, mutect2, varscan2
- LYPLAL1 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV65107072; called by muse, mutect2
- MACROD2 | c.862G>T p.E288* (on ENST00000642719; = p.E260* on NM_080676.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/454 reads (5%) | catalogued as COSV54072569; called by muse, mutect2
- NELFA | c.650G>A p.R217Q (on ENST00000542778; = p.R206Q on NM_005663.5) | Missense Mutation (SNP) | VAF 131/442 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs1370418534, COSV61605360; called by muse, mutect2, varscan2
- NLGN2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 733/832 reads (88%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs753026024; called by muse, mutect2, varscan2
- NPC1 | c.3394G>A p.A1132T | Missense Mutation (SNP) | VAF 191/449 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs1046046139, CM146145; called by muse, mutect2, varscan2
- ONECUT2 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 271/631 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1320317607; called by muse, mutect2, varscan2
- OR10J5 | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 122/357 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.217); catalogued as COSV58386636; called by muse, mutect2, varscan2
- OR10R2 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 26/349 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV100936790; called by muse, mutect2
- OSGIN2 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 166/475 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750953355, COSV52408294; called by muse, mutect2, varscan2
- PCDHGA2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 397/467 reads (85%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.014); catalogued as COSV53899200; called by muse, mutect2, varscan2
- PIANP | c.311G>A p.W104* | Nonsense Mutation (SNP) | VAF 220/592 reads (37%) | catalogued as rs780798121; called by muse, varscan2
- PIK3R1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 37/337 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV57137719; called by muse, mutect2
- RFX6 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 127/748 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.548); catalogued as rs1415549195; called by muse, mutect2, varscan2
- RNF157 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 50/636 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs377719776; called by muse, mutect2
- RP1L1 | c.448A>C p.T150P | Missense Mutation (SNP) | VAF 40/529 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs377360026, COSV61445053; called by muse, mutect2
- RYR1 | c.7029C>T p.G2343= | Splice Region (SNP) | VAF 179/462 reads (39%) | catalogued as rs138617219; called by muse, mutect2, varscan2
- SAMM50 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100601473; called by muse, mutect2
- SCRN2 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 173/438 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368479709; called by muse, mutect2, varscan2
- SEL1L2 | c.1001C>A p.A334E | Missense Mutation (SNP) | VAF 194/612 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV53155335; called by muse, mutect2, varscan2
- SIPA1L1 | c.3313C>T p.P1105S | Missense Mutation (SNP) | VAF 209/467 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs1207955821; called by muse, mutect2, varscan2
- SLAMF8 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 284/611 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763262299, COSV56989707; called by muse, mutect2, varscan2
- SNCAIP | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as rs534709742, COSV54401767; called by muse, mutect2, varscan2
- SOX6 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 149/347 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV57038719; called by muse, mutect2, varscan2
- SPINT4 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 77/377 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as rs772086277, COSV54142724, COSV54143294; called by muse, mutect2, varscan2
- ST6GAL2 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 242/532 reads (45%) | PolyPhen benign (0.005); catalogued as COSV64526997; called by muse, mutect2, varscan2
- SYNPO2L | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 158/368 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs751128243; called by muse, mutect2, varscan2
- TAF1L | c.3926C>T p.S1309L | Missense Mutation (SNP) | VAF 34/509 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.282); catalogued as rs759375951, COSV99645178; called by muse, mutect2
- TBC1D2 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 124/329 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201501022; called by muse, varscan2
- TJAP1 | c.1247G>A p.R416Q (on ENST00000372445 / NM_001146016.1; = p.R406Q on NM_080604.3) | Missense Mutation (SNP) | VAF 290/912 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as rs149804539, COSV99447380; called by muse, mutect2, varscan2
- TP53 | c.876_877insT p.G293Wfs*13 | Frame Shift Ins (INS) | VAF 362/650 reads (56%) | catalogued as COSV53319873; called by pindel, varscan2
- TRPS1 | c.2783C>T p.S928L (on ENST00000220888 / NM_001330599.2; = p.S941L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748664291; called by muse, mutect2, varscan2
- UBOX5 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 104/789 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs770694906; called by muse, mutect2, varscan2
- UNC79 | c.5530G>C p.A1844P (on ENST00000393151 / NM_001346218.2; = p.A1667P on NM_020818.5) | Missense Mutation (SNP) | VAF 63/464 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV56402405; called by muse, mutect2, varscan2
- WNT8A | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 121/410 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs368752673; called by muse, mutect2, varscan2
- XRRA1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 186/480 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs376452507; called by muse, mutect2, varscan2
- ZFHX3 | c.877T>C p.Y293H | Missense Mutation (SNP) | VAF 42/587 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1204366489; called by muse, mutect2
- ZNF423 | c.2243C>T p.A748V (on ENST00000563137 / NM_001379286.1; = p.A740V on NM_015069.4) | Missense Mutation (SNP) | VAF 168/408 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs923711687, COSV52176934; called by muse, mutect2, varscan2
- ZNF624 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 135/352 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as rs748562911; called by muse, mutect2, varscan2
- ZNF831 | c.3729G>C p.Q1243H | Missense Mutation (SNP) | VAF 95/628 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1568760361; called by muse, mutect2, varscan2
- ZSWIM4 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 190/428 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV54324098; called by muse, mutect2, varscan2
- ABHD17C | c.294_313del p.Y99Rfs*120 | Frame Shift Del (DEL) | VAF 218/563 reads (39%) | called by mutect2, pindel, varscan2
- ACTR3B | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGFG2 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 97/1244 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.708); called by muse, mutect2
- AMER2 | c.770G>C p.R257P | Missense Mutation (SNP) | VAF 568/910 reads (62%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APC2 | c.6439C>T p.R2147W | Missense Mutation (SNP) | VAF 168/472 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- ATP6V0A4 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BPIFB2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 40/1026 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2
- CALHM5 | c.818A>G p.Q273R | Missense Mutation (SNP) | VAF 31/953 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2
- CBLL2 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 197/330 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- CDC27 | c.2391C>T p.I797= | Splice Region (SNP) | VAF 48/159 reads (30%) | called by muse, mutect2, varscan2
- CDKL2 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CDON | c.3158T>C p.V1053A | Missense Mutation (SNP) | VAF 200/461 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEMIP2 | c.470G>C p.G157A | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL4A4 | c.2723_2732del p.R908Lfs*39 | Frame Shift Del (DEL) | VAF 107/298 reads (36%) | called by mutect2, pindel, varscan2
- COL6A1 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 318/431 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- DCLK1 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 108/603 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DCT | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 146/594 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, varscan2
- DDX3X | c.1468A>T p.K490* (on ENST00000399959; = p.K491* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 133/160 reads (83%) | called by muse, mutect2, varscan2
- DGKB | c.31A>T p.S11C | Missense Mutation (SNP) | VAF 37/513 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- DUS1L | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ELAPOR2 | c.308G>A p.C103Y (on ENST00000450689 / NM_001142749.3; = p.M1? on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FASTKD2 | c.989del p.E330Gfs*2 | Frame Shift Del (DEL) | VAF 58/156 reads (37%) | called by mutect2, pindel, varscan2
- FGB | c.537C>A p.H179Q | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GABBR1 | c.558G>C p.Q186H | Missense Mutation (SNP) | VAF 356/901 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GARNL3 | c.2093G>C p.R698T | Missense Mutation (SNP) | VAF 112/248 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- GOLGA1 | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 213/517 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA6A | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 120/578 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); called by mutect2, varscan2
- GPHB5 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- JHY | c.1621T>G p.L541V | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- KBTBD3 | c.1015A>G p.S339G | Missense Mutation (SNP) | VAF 114/334 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KCNA3 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 177/501 reads (35%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- LNPK | c.71A>C p.E24A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- LRBA | c.3598G>C p.A1200P | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST4 | c.6456C>A p.C2152* (on ENST00000403625 / NM_001164664.2; = p.C1963* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 218/626 reads (35%) | called by muse, mutect2, varscan2
- METTL11B | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSANTD2 | c.235T>G p.S79A | Missense Mutation (SNP) | VAF 210/526 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by mutect2, varscan2
- N4BP2L1 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 58/992 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- NBEA | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NSD3 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 163/397 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- OR5C1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 218/514 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PAK4 | c.853G>C p.G285R | Missense Mutation (SNP) | VAF 212/616 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.536); called by muse, varscan2
- PCDHB4 | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 219/623 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PDSS1 | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PERCC1 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 171/557 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHYHIPL | c.731A>T p.D244V | Missense Mutation (SNP) | VAF 161/337 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R1C | c.288A>C p.E96D | Missense Mutation (SNP) | VAF 124/301 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- PRAMEF14 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 231/498 reads (46%) | SIFT tolerated (0.96); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PTPRO | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RFX1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 48/560 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGPD3 | c.2992G>A p.G998S | Missense Mutation (SNP) | VAF 112/431 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RINL | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RUNX1T1 | c.514G>A p.A172T (on ENST00000265814 / NM_001198628.1; = p.A145T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SBF2 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SFSWAP | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SHF | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 264/619 reads (43%) | called by muse, mutect2, varscan2
- SLIT2 | c.3931C>T p.L1311F | Missense Mutation (SNP) | VAF 189/461 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- SLITRK5 | c.399A>T p.R133S | Missense Mutation (SNP) | VAF 32/612 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SOX12 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 79/1569 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.138); called by muse, mutect2
- ST7 | c.1492C>A p.L498I (on ENST00000265437 / NM_021908.3; = p.L475I on NM_018412.4) | Missense Mutation (SNP) | VAF 58/373 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SVBP | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 109/294 reads (37%) | called by muse, mutect2, varscan2
- TEX22 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 150/495 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TNS1 | c.2660C>A p.A887E | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAF3 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 54/608 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.021); called by muse, mutect2
- UCKL1 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 145/855 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- WEE1 | c.776G>A p.W259* | Nonsense Mutation (SNP) | VAF 62/171 reads (36%) | called by muse, mutect2, varscan2
- XIRP2 | c.3736A>C p.S1246R (on ENST00000628543; = p.S1421R on NM_152381.6) | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZNF451 | c.2370G>T p.K790N | Missense Mutation (SNP) | VAF 173/554 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ZNF729 | c.456A>C p.K152N | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC011462.1 | c.63C>T p.T21= | Silent (SNP) | VAF 240/565 reads (42%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.2112C>T p.P704= | Silent (SNP) | VAF 88/296 reads (30%) | catalogued as rs781475456; called by muse, mutect2, varscan2
- ADRA1A | c.432C>T p.L144= | Silent (SNP) | VAF 38/645 reads (6%) | catalogued as rs1420047651, COSV52370273; called by muse, mutect2
- C22orf23 | c.63G>A p.K21= | Silent (SNP) | VAF 136/404 reads (34%) | catalogued as COSV99031074; called by muse, mutect2, varscan2
- CBL | c.1440G>A p.R480= | Silent (SNP) | VAF 80/254 reads (31%) | called by muse, mutect2, varscan2
- CDC42BPG | c.1821C>T p.A607= | Silent (SNP) | VAF 178/526 reads (34%) | catalogued as rs1222709578; called by muse, mutect2, varscan2
- CYFIP2 | c.3132C>T p.C1044= (on ENST00000616178 / NM_001291722.2; = p.C1019= on NM_014376.4) | Silent (SNP) | VAF 304/361 reads (84%) | catalogued as rs1001146014, COSV59036381; called by muse, mutect2, varscan2
- DDX60 | c.4023T>C p.D1341= | Silent (SNP) | VAF 36/411 reads (9%) | called by muse, mutect2
- DHX38 | c.696G>A p.S232= | Silent (SNP) | VAF 180/449 reads (40%) | catalogued as rs556379177; called by muse, mutect2, varscan2
- E4F1 | c.1311T>C p.C437= | Silent (SNP) | VAF 208/471 reads (44%) | catalogued as rs1366215004; called by muse, mutect2, varscan2
- EEF1A2 | c.921C>T p.N307= | Silent (SNP) | VAF 166/1192 reads (14%) | catalogued as rs1057522085; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFHC1 | c.699G>A p.K233= | Silent (SNP) | VAF 108/413 reads (26%) | called by muse, mutect2, varscan2
- ELAVL4 | c.144C>A p.L48= | Silent (SNP) | VAF 102/394 reads (26%) | called by muse, mutect2, varscan2
- EMILIN1 | c.2763G>A p.L921= | Silent (SNP) | VAF 44/570 reads (8%) | catalogued as COSV53156002; called by muse, mutect2
- EPHB1 | c.1542C>T p.Y514= | Silent (SNP) | VAF 153/530 reads (29%) | catalogued as rs781750969, COSV101213289; called by muse, mutect2, varscan2
- EXOC3L1 | c.678G>T p.V226= | Silent (SNP) | VAF 196/523 reads (37%) | called by muse, mutect2, varscan2
- FAM204A | c.660A>G p.A220= | Silent (SNP) | VAF 53/135 reads (39%) | called by muse, mutect2, varscan2
- GRM1 | c.3537C>T p.Y1179= | Silent (SNP) | VAF 146/743 reads (20%) | catalogued as COSV99264339; called by muse, mutect2, varscan2
- HDAC5 | c.339G>A p.L113= | Silent (SNP) | VAF 30/443 reads (7%) | called by muse, mutect2
- HELZ2 | c.6288G>A p.K2096= (on ENST00000467148 / NM_001037335.2; = p.K1527= on NM_033405.3) | Silent (SNP) | VAF 38/809 reads (5%) | called by muse, mutect2
- HPS1 | c.693G>A p.P231= | Silent (SNP) | VAF 116/278 reads (42%) | catalogued as rs768048552; called by muse, mutect2, varscan2
- HTR7 | c.630C>T p.S210= | Silent (SNP) | VAF 32/486 reads (7%) | catalogued as rs768673251, COSV53282881; called by muse, mutect2
- IL12RB1 | c.339C>T p.L113= | Silent (SNP) | VAF 192/429 reads (45%) | catalogued as COSV59096234; called by muse, mutect2, varscan2
- IQSEC1 | c.2343C>T p.F781= | Silent (SNP) | VAF 72/314 reads (23%) | called by muse, mutect2, varscan2
- LAMA2 | c.7426C>T p.L2476= | Silent (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
- LILRA1 | c.861G>A p.V287= | Silent (SNP) | VAF 301/1087 reads (28%) | called by muse, mutect2, varscan2
- MMP16 | c.1689A>G p.K563= | Silent (SNP) | VAF 124/586 reads (21%) | called by muse, mutect2, varscan2
- MTERF1 | c.960G>T p.V320= | Silent (SNP) | VAF 174/340 reads (51%) | called by muse, mutect2, varscan2
- NIPAL4 | c.147C>A p.G49= | Silent (SNP) | VAF 224/647 reads (35%) | called by muse, mutect2, varscan2
- NPR1 | c.21C>T p.P7= | Silent (SNP) | VAF 225/517 reads (44%) | catalogued as rs1010240659; called by muse, mutect2, varscan2
- OR52L1 | c.912G>A p.A304= | Silent (SNP) | VAF 186/412 reads (45%) | catalogued as rs780095253, COSV59985658; called by muse, mutect2
- RFC2 | c.315C>T p.L105= | Silent (SNP) | VAF 38/564 reads (7%) | called by muse, mutect2
- RFPL3 | c.702T>A p.T234= (on ENST00000249007 / NM_001098535.1; = p.T205= on NM_006604.2) | Silent (SNP) | VAF 174/591 reads (29%) | called by muse, mutect2, varscan2
- SCAMP2 | c.435C>T p.Y145= | Silent (SNP) | VAF 119/342 reads (35%) | called by muse, mutect2, varscan2
- SLC30A5 | c.933T>C p.I311= | Silent (SNP) | VAF 164/363 reads (45%) | called by muse, mutect2, varscan2
- SOX11 | c.651C>G p.V217= | Silent (SNP) | VAF 222/484 reads (46%) | called by muse, varscan2
- SPATA7 | c.591C>A p.A197= | Silent (SNP) | VAF 56/485 reads (12%) | catalogued as COSV99248515; called by muse, mutect2, varscan2
- STX11 | c.669C>T p.D223= | Silent (SNP) | VAF 250/1055 reads (24%) | catalogued as COSV62448558; called by muse, mutect2, varscan2
- TAOK1 | c.975A>T p.A325= | Silent (SNP) | VAF 102/248 reads (41%) | called by mutect2, varscan2
- TMEM215 | c.642G>A p.P214= | Silent (SNP) | VAF 151/338 reads (45%) | catalogued as rs140964705; called by muse, mutect2, varscan2
- TMPRSS2 | c.273G>C p.L91= | Silent (SNP) | VAF 209/315 reads (66%) | catalogued as COSV100151312; called by muse, mutect2, varscan2
- TNPO2 | c.2064G>T p.L688= | Silent (SNP) | VAF 137/405 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.52635C>T p.P17545= (on ENST00000591111; = p.P10121= on NM_003319.4) | Silent (SNP) | VAF 117/267 reads (44%) | catalogued as rs768333256; called by muse, mutect2, varscan2
- TUT4 | c.3081T>C p.C1027= | Silent (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- VWC2 | c.768G>A p.Q256= | Silent (SNP) | VAF 257/523 reads (49%) | catalogued as COSV100514135, COSV61491580; called by muse, mutect2, varscan2
- ZNF519 | c.651T>G p.T217= | Silent (SNP) | VAF 64/150 reads (43%) | called by muse, mutect2, varscan2
- ZNF853 | c.1506C>T p.R502= | Silent (SNP) | VAF 505/898 reads (56%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.168C>G p.A56= | Silent (SNP) | VAF 258/641 reads (40%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851232 C>T | 3'Flank (SNP) | VAF 152/214 reads (71%) | catalogued as rs761574481; called by muse, mutect2, varscan2
- ATAD3B | c.*513G>C | 3'UTR (SNP) | VAF 181/580 reads (31%) | catalogued as rs1040128103; called by muse, mutect2
- CCDC57 | c.2564-11721G>C | Intron (SNP) | VAF 114/382 reads (30%) | called by muse, mutect2, varscan2
- DUBR | n.217G>A | RNA (SNP) | VAF 218/637 reads (34%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.988-26077A>T | Intron (SNP) | VAF 155/652 reads (24%) | catalogued as rs1166033529; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37515G>A | Intron (SNP) | VAF 246/618 reads (40%) | catalogued as rs946239245, COSV50126066; called by muse, mutect2
- MARCHF10 | c.383-2420C>T | Intron (SNP) | VAF 138/351 reads (39%) | catalogued as rs368791164; called by muse, mutect2, varscan2
- SLC22A17 | n.1419G>A | RNA (SNP) | VAF 220/488 reads (45%) | catalogued as rs774606059, COSV99249147; called by muse, varscan2
- TTLL11 | c.1539+26_1539+53del | Intron (DEL) | VAF 101/341 reads (30%) | called by mutect2, pindel, varscan2
- TTN | c.10360+2680C>T | Intron (SNP) | VAF 78/199 reads (39%) | catalogued as rs200935937; ClinVar: uncertain significance; called by muse, mutect2, varscan2
